Somatic mutation profile of tumor specimen 0DLDZR from CCDI case PBBZEA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.1 years (3,692 days).
Specimen 0DLDZR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16b05e1d-9c1b-475e-bb86-3f7951c1685d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLDZB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f43c55a0-b475-4249-bacc-86c40faf6dcc

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, Frame Shift Ins 3, Intron 2, Nonsense Mutation 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT | c.577dup p.L193Pfs*32 | Frame Shift Ins (INS) | VAF 50/282 reads (18%) | catalogued as rs180177241; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ABCA5 | c.128dup p.L43Ffs*8 | Frame Shift Ins (INS) | VAF 200/778 reads (26%) | catalogued as rs751512043; called by mutect2, varscan2
- CCR5 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 467/1067 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs1017863136, COSV52751345; called by muse, mutect2, varscan2
- HGFAC | c.544C>A p.Q182K | Missense Mutation (SNP) | VAF 251/541 reads (46%) | SIFT tolerated (0.88); PolyPhen benign (0.012); catalogued as COSV58749390; called by muse, mutect2, varscan2
- MTSS1 | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 155/375 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.123); catalogued as rs759302505, COSV61497476; called by muse, mutect2, varscan2
- NLRP2 | c.1759C>T p.R587* | Nonsense Mutation (SNP) | VAF 136/247 reads (55%) | catalogued as rs777564374; called by muse, mutect2, varscan2
- PTEN | c.477G>C p.R159S | Missense Mutation (SNP) | VAF 20/484 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64288957, COSV64298985; called by muse, mutect2
- SCN10A | c.4744C>T p.R1582C | Missense Mutation (SNP) | VAF 372/845 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs569261408, COSV71861065; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC23A2 | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 454/965 reads (47%) | catalogued as rs773602594; called by muse, mutect2, varscan2
- SLFN11 | c.1940G>A p.R647Q | Missense Mutation (SNP) | VAF 270/960 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201150761, COSV57698504; called by muse, mutect2, varscan2
- DNAH17 | c.7039T>C p.Y2347H | Missense Mutation (SNP) | VAF 221/720 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GTF2I | c.2794T>C p.S932P (on ENST00000573035 / NM_032999.4; = p.S891P on NM_001518.5) | Missense Mutation (SNP) | VAF 501/1097 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR6Y1 | c.107dup p.L37Pfs*21 | Frame Shift Ins (INS) | VAF 287/611 reads (47%) | called by mutect2, varscan2
- RBM20 | c.1468C>T p.P490S | Missense Mutation (SNP) | VAF 395/420 reads (94%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TGFBR3 | c.687T>A p.N229K | Missense Mutation (SNP) | VAF 435/982 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLEC16A | c.1614G>A p.P538= | Silent (SNP) | VAF 345/798 reads (43%) | catalogued as rs756478264; called by muse, mutect2, varscan2
- GOLGA6L4 | c.9C>T p.P3= | Silent (SNP) | VAF 290/762 reads (38%) | called by mutect2, varscan2
- KCNU1 | c.915G>A p.A305= | Silent (SNP) | VAF 102/1146 reads (9%) | catalogued as rs766597978, COSV67753185; called by muse, mutect2
- KEAP1 | c.87C>T p.D29= | Silent (SNP) | VAF 26/247 reads (11%) | catalogued as rs746477922; called by muse, mutect2, varscan2
- CEACAM19 | c.-57dup | 5'UTR (INS) | VAF 41/84 reads (49%) | called by mutect2, varscan2
- L3MBTL3 | c.2136+98dup | Intron (INS) | VAF 76/212 reads (36%) | catalogued as rs1168436883; called by mutect2, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 4/59 reads (7%) | called by muse, mutect2
